Surgical pathology report (de-identified scan), TCGA case TCGA-G3-A25Z, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Alberta Health Services, specimen TCGA-G3-A25Z-01A (Primary Tumor).

[page 1 of 2]
ICD-0-3

carcinoma, hepatocellular, nos 8170/3

Site: liver C22-0 lw 4/25/11

MRN:

PHN:

ACB:

DOB/Gender:

Telephone:

Encounter:

Location:

Ordering:

Surgical Pathology Report

Inquiry Numbers:

Accession Number:

Collected Date:

Pathologist:

Received Date/Time:

Specimen Description

A. Gallbladder

B. Liver

Clinical Information

Hepatocellular carcinoma, hepatitis B

Diagnosis

A. Gallbladder:

- No pathologic diagnosis.

B. Liver:

- Chronic hepatitis B of mild activity (Grade 2).
- Fibrosis, severe, (Stage 3).
- Hepatocellular carcinoma, moderately differentiated, 3.0 cm in the greatest dimension (progressed type), completely excised. No

Cc:

Chart Request ID:

Print Date/Time:

www.

Pathology: Provider - Permanent

Page 1 of 2

[page 2 of 2]
Location:

MRN:

PHN:

ACB:

Surgical Pathology Report

Inquiry Numbers:

Accession Number:

Collected Date:

Pathologist:

Received Date/Time:

evidence of endothelium-lined space invasion.

Reported by:

Electronically signed by:

Verified:

Gross Description

Received are specimens A to B. All requisitions and specimen containers are labelled with the patient's name. The cassettes and AP identifiers are labelled with the Surgical Number.

A. The specimen is received fresh and is subsequently placed into formalin and consists of an intact gallbladder measuring 7.5 x 4.0 x 3.0 cm. The serosal surface is tan and smooth. The lumen contains bile. Calculi are not grossly identified. The mucosal surface is bile stained and velvety. The wall averages 0.2 cm in thickness. The cystic duct is patent. The cystic duct lymph node is identified. Representative sections are submitted in one cassette.

B. The specimen is received fresh and is subsequently placed into formalin and consists of a portion of liver weighing 101.8 g and measuring 10 x 6 x 5.4 cm. The resection margin is dyed blue. Upon sectioning a firm tan mass is identified measuring 3.0 x 2.0 x 1.7 cm. This mass is located 0.5 cm from the capsular surface and comes within 1.0 cm of the blue painted resection margin. The remainder of the liver parenchyma is grossly unremarkable. Representative sections are submitted as follows:

B1 - section of the mass in relation to the capsular surface.

B2 - section of the mass in relation to the closest blue painted margin.

B3 - further section of the mass.

B4 - section of grossly unremarkable liver parenchyma.

One section was also submitted for the study.

Cc:

Chart Request ID:

Print Date/Time:

Pathology: Provider - Permanent

Page 2 of 2

www.

Source: NCI Genomic Data Commons file 682426e3-e926-4e98-97b4-1b89ead97336 (TCGA-G3-A25Z.001A2553-3F5F-4A74-88E6-03B42C061E6D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).